Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6BG, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6BG-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

* Addendum *

Patient: [REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

ICD-O-3
Liposarcoma, dedifferentiated
8858/3
Site: Retroperitoneum
C48.0
JW 5/21/13

Clinical Diagnosis & History:

Patient with large right retroperitoneal mass; c/w liposarcoma on biopsy.

Specimens Submitted:

1: Right retroperitoneal mass with right colectomy

DIAGNOSIS:

1. Retroperitoneum, right colon, mass, resection:

- Dedifferentiated liposarcoma arising in a background of a well differentiated liposarcoma.
- Tumor measures 10.8 cm in greatest dimension.
- Dedifferentiated component constitutes greater than 98% of the mass and shows a high grade spindle and pleomorphic sarcoma.
- Tumor involves the colonic wall.
- Necrosis is present.
- Tumor is covered by a thin fibrous capsule that forms the margin.
- Separate well differentiated liposarcoma (6 cm), with extensive fat necrosis, involving the spermatic cord.
- Surgical resection margins are uninvolved.
- Appendix is unremarkable.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "Right retroperitoneal mass with right colectomy", and consists of a portion of colon measuring 21 cm in length x 5.2 cm in circumference, with an intact vermiform appendix attached to the cecum measuring 11 x 0.6 cm. There is a portion of spermatic cord that measures 6.5 x 3 cm. Adjacent to the spermatic cord and 6.5 cm from the margin, there is a well circumscribed, yellow firm adipose tissue mass, measuring 6 x 5.8 x 5.1 cm and inked in blue. There is a second larger well

** Continued on next page **

[page 2 of 3]
SURGICAL

----- Page 2 of 3
circumscribed, pink to yellow firm lobulated tumor mass with central
necrosis that comprises approximately 40%, and measures 10.8 x 7.6 x 7.3 cm.
The tumor arises from the pericolonic adipose tissue, 10 cm away from the
cecum and 4 cm from the distal colonic resection margin. Attached to the
mass there is a 3.9 x 2.7 x 1.8 cm lymph node. Both tumors are covered by a
thin fibrous capsule. There is muscle attached to the adipose tissue
measuring 10.7 x 10.3 cm. Representative sections are submitted after TPS
and picture were taken.

Summary of sections:

PM- proximal margin

DM- distal margin

T1-small mass

T2-large mass

T1C- small mass in relation to the spermatic cord

T2C- large mass in relation to the colon

AP-appendix

SM- spermatic cord in relation to the mass

SCM-spermatic cord margin

Summary of Sections:

Part 1: Right retroperitoneal mass with right colectomy

Block	Sect. Site	PCs
1	APP	1
1	DM	1
1	PM	1
1	SCM	1
2	SM	2
5	T1	5
1	T1C	1
10	T2	10
1	T2C	1

Procedures/Addenda:

Addendum

Date Ordered:

Status: Signed Out

Date Complete:

Date Reported:

Addendum Diagnosis

1. Retroperitoneum and right colon, mass, resection:

- Immunohistochemical stains for CDK4 and MDM2 are positive in the
tumor cells.

Addendum Comment

Some of the immunohistochemistry and ISH tests were developed and their

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY
[Redacted]
[Redacted]
[Redacted]

[Redacted]
[Redacted]
[Redacted]

----- Page 3 of 3
performance characteristics were determined by the Department of Pathology.
They have not been cleared or approved by the US Food and Drug
Administration. The FDA has determined that such clearance or approval is
not necessary. These tests are used for clinical purposes. They should not
be regarded as investigational or for research. This laboratory is certified
under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as
qualified to perform high complexity clinical laboratory testing.

*** Report Electronically Signed Out ***
Signed out by

** End of Report **

Criteria	W 5/2/13	Yes	No

Source: NCI Genomic Data Commons file 51667813-f4d0-4c3a-bed2-ab50b0a22f03 (TCGA-DX-A6BG.BBCD8C5C-E7AF-47E0-8780-F31E90134600.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).